Somatic mutation profile of tumor specimen MP2PRT-PASVAF-TMP1-A (aliquot MP2PRT-PASVAF-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVAF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,185 days).
Specimen MP2PRT-PASVAF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c629212-b306-4d42-b9a9-71d4effefeb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVAF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVAF-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a1e3f47-0974-4207-b302-4d2f962bc187

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/268 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/387 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- BECN2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 35/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1220380780; called by muse, mutect2
- C3 | c.4186C>A p.Q1396K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.027); catalogued as rs1324291628; called by muse, mutect2, varscan2
- CCDC17 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs753067276, COSV51972158; called by muse, mutect2, varscan2
- MUC12 | c.13063G>A p.V4355I (on ENST00000379442; = p.V4212I on NM_001164462.1) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.24); catalogued as rs199664042; called by muse, mutect2, varscan2
- NRG1 | c.240C>G p.F80L (on ENST00000523534; = p.F227L on NM_013962.2) | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV73059882; called by muse, mutect2, varscan2
- BCLAF3 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BECN2 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2
- CDS1 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CNTNAP2 | c.3000T>A p.F1000L | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DCBLD1 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 107/245 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FURIN | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCH | c.1602T>G p.I534M | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NDNF | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PDZD4 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.053); called by muse, mutect2
- PKDREJ | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRR23C | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 46/556 reads (8%) | called by muse, mutect2
- TCHH | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 61/712 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- TCHH | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.078); called by muse, mutect2
- ANKRD18A | c.2901G>A p.T967= | Silent (SNP) | VAF 60/210 reads (29%) | catalogued as rs889888942; called by muse, mutect2, varscan2
- CACNA1H | c.420C>T p.D140= | Silent (SNP) | VAF 103/228 reads (45%) | catalogued as rs1357455193, COSV62005421; called by muse, mutect2, varscan2
- LBR | c.1320G>A p.A440= | Silent (SNP) | VAF 54/235 reads (23%) | catalogued as rs754636043; called by muse, mutect2, varscan2
- PAX9 | c.213C>T p.I71= | Silent (SNP) | VAF 32/510 reads (6%) | catalogued as COSV64062440; called by muse, mutect2
- TCHH | c.1902G>A p.L634= | Silent (SNP) | VAF 72/558 reads (13%) | catalogued as COSV100915409; called by muse, mutect2, varscan2
- WNK2 | c.6664C>T p.L2222= (on ENST00000297954 / NM_001282394.1; = p.L2185= on NM_006648.3) | Silent (SNP) | VAF 15/574 reads (3%) | called by muse, mutect2
- AL353804.7 | chrX:73849787 G>C | 5'Flank (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
